Somatic mutation profile of tumor specimen C3L-06209-01 (aliquot CPT0504970009) from CPTAC case C3L-06209, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.8 years (26,574 days).
Specimen C3L-06209-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fafef567-2849-46f6-b977-730cb50ceb86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06209-31 (Blood Derived Normal), aliquot CPT0504960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89993e01-2f12-436f-bc2d-7a1a74f8e2d7

The open-access MAF lists 116 somatic variants for this specimen: 87 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 25, Nonsense Mutation 3, Splice Region 3, Intron 2, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 23/474 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 32/384 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/274 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 47/521 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- ATRNL1 | c.949A>C p.M317L | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as rs199717810; called by muse, mutect2
- CCDC172 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV60937379, COSV60940500; called by muse, mutect2
- CNTN4 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV68580113; called by muse, mutect2
- CPQ | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 30/509 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs757303134, COSV55137584; called by muse, mutect2
- DPP10 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 20/290 reads (7%) | catalogued as COSV59661675; called by muse, mutect2
- EFCAB6 | c.4321C>T p.R1441C | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372168931, COSV53061785, COSV53066189; called by muse, mutect2
- EPB41L3 | c.3213A>T p.K1071N | Missense Mutation (SNP) | VAF 31/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2
- FAM13A | c.1271+1G>A p.X424_splice | Splice Site (SNP) | VAF 24/276 reads (9%) | catalogued as rs1229556845; called by muse, mutect2
- FATE1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs748489127, COSV64848901; called by muse, mutect2, varscan2
- FGF13 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as COSV59547704; called by muse, mutect2
- FOXN4 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 34/585 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200708160, COSV54492473; called by muse, mutect2
- GALNT17 | c.871T>G p.S291A | Missense Mutation (SNP) | VAF 38/570 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV100354141; called by muse, mutect2
- GJA4 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745666312, COSV60724691; called by muse, mutect2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2
- GRM6 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1207061592; called by muse, mutect2
- MAVS | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 33/673 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs370132622; called by muse, mutect2
- MUC2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 42/591 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs907029763; called by muse, mutect2
- MYRIP | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs762800014, COSV56861487; called by muse, mutect2
- NUBP2 | c.600G>A p.T200= | Splice Region (SNP) | VAF 56/777 reads (7%) | catalogued as rs200434981; called by muse, mutect2
- OR2M5 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 27/417 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100822874; called by muse, mutect2
- OR4X1 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs144193033; called by muse, mutect2
- OR5B21 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 23/387 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64481639; called by muse, mutect2
- OSR1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as rs1156697377; called by muse, mutect2
- PTPRN2 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs368579481; called by muse, mutect2
- PYGM | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 34/466 reads (7%) | catalogued as CM991088; called by muse, mutect2
- RYR3 | c.10417G>A p.V3473I (on ENST00000389232; = p.V3474I on NM_001036.6) | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs201678035; called by muse, mutect2
- SCRIB | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 54/831 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as rs1039294225; called by muse, mutect2
- SEC16A | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 29/509 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766852818; called by muse, mutect2
- SEMA4A | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs200251591; called by muse, mutect2
- SERPINA12 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100369559; called by muse, mutect2
- SLC15A1 | c.981C>T p.T327= | Splice Region (SNP) | VAF 46/408 reads (11%) | catalogued as rs578118415; called by muse, mutect2, varscan2
- SLC15A3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 55/788 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as rs1210969926; called by muse, mutect2
- STKLD1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 23/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370999988; called by muse, mutect2
- SULF2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs765574446, COSV100737347; called by muse, mutect2
- SYT9 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778982022, COSV59614771; called by muse, mutect2
- TAS2R13 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV66831685; called by muse, mutect2
- TEC | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs369398035, COSV101202634; called by muse, mutect2
- TGFBR1 | c.99G>A p.A33= | Splice Region (SNP) | VAF 20/207 reads (10%) | catalogued as rs779055286, COSV66625361; ClinVar: likely benign; called by muse, mutect2
- TMEM53 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs146173030; called by muse, mutect2
- TRPC5 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV53283771, COSV53303581; called by muse, mutect2, varscan2
- TTN | c.22551A>C p.E7517D (on ENST00000591111; = p.E6590D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/442 reads (7%) | PolyPhen benign (0); catalogued as COSV60416470; called by muse, mutect2
- ZFHX3 | c.6584A>T p.N2195I | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455202356; called by muse, mutect2
- ZNF492 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV71761752, COSV71761974; called by muse, varscan2
- ZNF497 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs955087098, COSV54051129; called by muse, mutect2
- AMER2 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 69/591 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ARHGAP39 | c.2632G>A p.A878T (on ENST00000276826 / NM_001308208.2; = p.A909T on NM_025251.2) | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ASTE1 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- ATP2B1 | c.1872C>A p.F624L | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); called by muse, mutect2
- CAPNS2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2
- CBLN1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 31/600 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2
- COL3A1 | c.3386C>A p.A1129E | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); called by muse, mutect2
- EIF3A | c.2573A>G p.K858R | Missense Mutation (SNP) | VAF 35/560 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- FAM20B | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FBXO38 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCRLB | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- FOXD3 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 42/585 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- HERC1 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- IAH1 | c.394A>C p.T132P | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- KBTBD11 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 46/804 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2
- KIF1A | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 35/580 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2
- MSH6 | c.2029A>C p.S677R | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.145); called by muse, mutect2
- NLGN4Y | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- NOVA2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 38/619 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.351); called by muse, mutect2
- NOXO1 | c.904G>A p.G302R (on ENST00000397280 / NM_172168.3; = p.G296R on NM_144603.4) | Missense Mutation (SNP) | VAF 48/706 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- OR11H2 | c.535G>A p.D179N (on ENST00000556246; = p.D190N on NM_001197287.1) | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); called by muse, mutect2
- PITRM1 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PLCH2 | c.167T>G p.V56G | Missense Mutation (SNP) | VAF 50/664 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- PLCZ1 | c.882A>G p.I294M | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2
- PLXNC1 | c.3292A>C p.K1098Q | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- PRAMEF20 | c.1023A>C p.Q341H | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- RHOV | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF139 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- SIDT2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 23/436 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- SLC12A2 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC5A11 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- SOD3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 19/627 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SSTR2 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ST6GAL2 | c.1567A>C p.S523R | Missense Mutation (SNP) | VAF 17/330 reads (5%) | PolyPhen benign (0); called by muse, mutect2
- TCF15 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TRIM42 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 62/555 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.382); called by muse, mutect2
- VCX3B | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ZNF302 | c.629A>C p.K210T (on ENST00000627982; = p.K131T on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.166); called by muse, mutect2
- ZNF99 | c.1855A>G p.K619E | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- ADCY5 | c.2163C>T p.G721= | Silent (SNP) | VAF 29/495 reads (6%) | catalogued as rs773115066; called by muse, mutect2
- C11orf87 | c.435C>T p.N145= | Silent (SNP) | VAF 39/600 reads (7%) | catalogued as COSV59357736; called by muse, mutect2
- CHTOP | c.312C>T p.G104= | Silent (SNP) | VAF 28/486 reads (6%) | called by muse, mutect2
- EEF1A1 | c.21T>C p.H7= | Silent (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2, varscan2
- FGF6 | c.282C>T p.I94= | Silent (SNP) | VAF 29/468 reads (6%) | catalogued as rs201860096; called by muse, mutect2
- FGL2 | c.465T>C p.H155= | Silent (SNP) | VAF 48/431 reads (11%) | catalogued as COSV50380309; called by muse, mutect2, varscan2
- GREB1 | c.1041G>A p.P347= | Silent (SNP) | VAF 23/430 reads (5%) | catalogued as rs762648862, COSV99302779; called by muse, mutect2
- GRM1 | c.3237G>A p.P1079= | Silent (SNP) | VAF 43/630 reads (7%) | called by muse, mutect2
- HGS | c.1245C>T p.A415= | Silent (SNP) | VAF 37/465 reads (8%) | catalogued as rs771492798; called by muse, mutect2
- HSPBP1 | c.490C>A p.R164= | Silent (SNP) | VAF 40/619 reads (6%) | called by muse, mutect2
- IFIT1B | c.612C>T p.H204= | Silent (SNP) | VAF 44/470 reads (9%) | catalogued as rs777499902; called by muse, mutect2
- LRRC74A | c.828G>A p.L276= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as COSV53608496; called by muse, mutect2
- LYSMD1 | c.267G>A p.E89= | Silent (SNP) | VAF 19/422 reads (5%) | called by muse, mutect2
- MAGI1 | c.3927C>T p.A1309= | Silent (SNP) | VAF 42/697 reads (6%) | catalogued as rs748431740; called by muse, mutect2
- MARCHF4 | c.180G>A p.A60= | Silent (SNP) | VAF 38/628 reads (6%) | catalogued as COSV99814147; called by muse, mutect2
- PIEZO1 | c.573G>A p.T191= | Silent (SNP) | VAF 38/602 reads (6%) | catalogued as rs1415627924; called by muse, mutect2
- SALL3 | c.408G>A p.A136= | Silent (SNP) | VAF 48/793 reads (6%) | catalogued as rs1282482508; called by muse, mutect2
- SEMA6C | c.537C>T p.A179= | Silent (SNP) | VAF 22/361 reads (6%) | called by muse, mutect2
- SERPINA1 | c.327G>A p.T109= | Silent (SNP) | VAF 38/684 reads (6%) | catalogued as rs764493280, COSV63345645; ClinVar: uncertain significance; called by muse, mutect2
- SLC45A1 | c.318G>A p.A106= | Silent (SNP) | VAF 48/512 reads (9%) | catalogued as rs751344756, COSV57094250; called by muse, mutect2
- SMG1 | c.8358G>A p.A2786= | Silent (SNP) | VAF 24/385 reads (6%) | catalogued as rs371413635; called by muse, mutect2
- SPSB4 | c.186G>T p.S62= | Silent (SNP) | VAF 56/652 reads (9%) | catalogued as COSV60147024; called by muse, mutect2
- SSTR2 | c.474G>A p.T158= | Silent (SNP) | VAF 24/494 reads (5%) | catalogued as rs371381814; called by muse, mutect2
- VAX1 | c.75G>A p.A25= | Silent (SNP) | VAF 24/474 reads (5%) | catalogued as COSV53329199; called by muse, mutect2
- WNT3A | c.276C>T p.H92= | Silent (SNP) | VAF 34/441 reads (8%) | catalogued as rs201572822; called by muse, mutect2
- ACP4 | chr19:50798306 G>A | 3'Flank (SNP) | VAF 19/655 reads (3%) | called by muse, mutect2
- APOBEC3B | c.1134+118C>T | Intron (SNP) | VAF 34/548 reads (6%) | catalogued as rs745999319; called by muse, mutect2
- ASIC2 | c.556-179587C>T | Intron (SNP) | VAF 42/671 reads (6%) | catalogued as rs945526715; called by muse, mutect2
- DIRC3 | n.272T>G | RNA (SNP) | VAF 20/326 reads (6%) | catalogued as rs1220193522, COSV70403961; called by muse, mutect2
